Somatic mutation profile of tumor specimen TARGET-10-PATGKE-09A (aliquot TARGET-10-PATGKE-09A-01D) from TARGET case TARGET-10-PATGKE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.5 years (4,202 days).
Specimen TARGET-10-PATGKE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bbdbaf7-0fa9-4a8c-b58e-be6da7186ea1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATGKE-10A (Blood Derived Normal), aliquot TARGET-10-PATGKE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eef02a67-ce37-416c-97de-ca3c69549d6d

The open-access MAF lists 10 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, Intron 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MROH2B | c.3589C>A p.Q1197K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV68182882; called by mutect2, varscan2
- TSHZ3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368424576; called by muse, mutect2
- CLDND1 | c.15dup p.A6Cfs*11 | Frame Shift Ins (INS) | VAF 49/145 reads (34%) | called by mutect2, pindel, varscan2
- CD300LD | c.90G>A p.S30= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as rs756980571; called by muse, mutect2, varscan2
- COL16A1 | c.1332G>T p.G444= | Silent (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- CRYBB2 | c.399C>T p.H133= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs770963171; called by muse, mutect2, varscan2
- SULT2A1 | c.270G>A p.T90= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs748360834, COSV99705481, COSV99705546; called by muse, mutect2, varscan2
- CES4A | c.1162-25A>G | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2
- DMD | c.6438+22del | Intron (DEL) | VAF 14/27 reads (52%) | called by mutect2, pindel, varscan2
- PHTF2 | c.*173dup | 3'UTR (INS) | VAF 16/36 reads (44%) | catalogued as rs994654391; called by mutect2, varscan2
